Gene-level copy-number profile of tumor specimen ALCH-AEPO-TTP1-A from ALCHEMIST case ALCH-AEPO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (19,000 days).
Specimen ALCH-AEPO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6eac4e74-3444-44f1-b516-2cdb4c4e0220.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEPO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/65320439-a3fc-464a-afb7-12f1853ccf98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 5,534; copy number 2: 52,621; copy number 3: 226; copy number 4: 4.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,203,503–228,213,664, 1 gene (within-gene range 0–2): OBSCN-AS1.
- chr2:130,139,287–130,182,750, 2 genes (within-gene range 0–2): CCDC74B, SMPD4.
- chr3:52,373,652–52,374,882, 1 gene (within-gene range 0–2): PPP2R5CP.
- chr4:3,441,968–3,449,486, 1 gene: HGFAC.
- chr8:24,950,955–24,957,110, 3 genes: NEFL, MIR6841, AC107373.2.
- chr16:1,206,560–1,207,124, 1 gene (within-gene range 0–1): AC120498.6.
- chr16:85,169,525–85,676,204, 1 gene (within-gene range 0–2): GSE1.
- chr16:85,659,378–85,659,675, 1 gene: RN7SL381P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
